Somatic mutation profile of tumor specimen C3L-02601-01 (aliquot CPT0128330006) from CPTAC case C3L-02601, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 71.5 years (26,133 days).
Specimen C3L-02601-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5a87269-7356-4202-9b29-1f1e1834359e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02601-31 (Blood Derived Normal), aliquot CPT0129450002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/158df1cc-0009-4cc2-9c82-01af3a0f1112

The open-access MAF lists 535 somatic variants for this specimen: 360 protein-altering or splice-affecting, 120 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 308, Silent 120, Intron 26, Nonsense Mutation 23, RNA 14, Frame Shift Del 11, Splice Site 8, 5'UTR 7, Splice Region 5, 5'Flank 4, 3'UTR 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AF196969.1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs104894800, CM990496; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 82/369 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC013477.1 | c.2184C>G p.D728E | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.357); catalogued as rs1002216345; called by muse, mutect2
- ACOT7 | c.53C>A p.S18Y | Missense Mutation (SNP) | VAF 38/369 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV100830220; called by muse, mutect2, varscan2
- ADGRB1 | c.2452G>T p.E818* | Nonsense Mutation (SNP) | VAF 28/138 reads (20%) | catalogued as COSV60103195; called by muse, mutect2, varscan2
- ADGRB1 | c.4187G>T p.R1396L | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.931); catalogued as rs764161080, COSV100030589; called by muse, mutect2
- ADGRL2 | c.1745C>A p.P582H | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99587149; called by muse, mutect2, varscan2
- AL592490.1 | c.2254C>G p.L752V | Missense Mutation (SNP) | VAF 31/268 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as COSV69428169; called by muse, mutect2, varscan2
- ANK2 | c.8725C>G p.P2909A | Missense Mutation (SNP) | VAF 111/845 reads (13%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.443); catalogued as COSV52162583; called by muse, mutect2, varscan2
- ANK3 | c.1954G>C p.E652Q | Missense Mutation (SNP) | VAF 49/604 reads (8%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as COSV55049050; called by muse, mutect2
- ARFGEF3 | c.6503G>T p.R2168M | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52461732, COSV52466737; called by muse, mutect2, varscan2
- ARHGAP20 | c.2527C>T p.R843W | Missense Mutation (SNP) | VAF 39/371 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52820474; called by muse, mutect2, varscan2
- ARHGAP35 | c.3871G>C p.E1291Q | Missense Mutation (SNP) | VAF 38/416 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV68329474; called by muse, mutect2
- ASPM | c.6700C>G p.Q2234E | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.519); catalogued as COSV99660456; called by muse, mutect2, varscan2
- ATM | c.6814G>A p.E2272K | Missense Mutation (SNP) | VAF 27/281 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs886039471, CM030779, COSV53744239, COSV99588352; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2A1 | c.2398G>A p.D800N | Missense Mutation (SNP) | VAF 75/598 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs752797728, COSV62868759; called by muse, mutect2, varscan2
- ATP7B | c.3835G>A p.D1279N | Missense Mutation (SNP) | VAF 27/708 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.717); catalogued as CM053786; called by muse, mutect2
- BACH1 | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 60/440 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.266); catalogued as COSV54521862; called by muse, mutect2, varscan2
- BUD23 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 35/405 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1334787119, COSV56096154; called by muse, mutect2
- C1orf141 | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 47/426 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100924330; called by muse, mutect2, varscan2
- CACNA1E | c.4382C>T p.P1461L | Missense Mutation (SNP) | VAF 38/326 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62413949, COSV62438536; called by muse, varscan2
- CAPN15 | c.89G>T p.R30L | Missense Mutation (SNP) | VAF 50/383 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs778703576; called by muse, mutect2, varscan2
- CCDC14 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.783); catalogued as rs1050675578; called by muse, mutect2, varscan2
- CD163L1 | c.3950G>A p.G1317E | Missense Mutation (SNP) | VAF 52/529 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867081460, COSV58011299; called by muse, mutect2, varscan2
- CD5L | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.387); catalogued as rs749437803, COSV100941234; called by muse, mutect2, varscan2
- CDHR3 | c.1921G>C p.D641H | Missense Mutation (SNP) | VAF 56/734 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746415660; called by muse, mutect2
- CEP135 | c.1552T>C p.Y518H | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1319962027; called by muse, mutect2
- CFAP20 | c.21G>C p.Q7H | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); catalogued as COSV99343396; called by muse, mutect2
- CFAP20DC | c.2202G>C p.Q734H (on ENST00000482387 / NM_001351530.2; = p.Q483H on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/400 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768140092; called by muse, mutect2
- CFHR5 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 32/263 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56825945; called by muse, mutect2, varscan2
- CMTM3 | c.116C>G p.S39C | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1272913749; called by muse, mutect2, varscan2
- CNTNAP4 | c.2540C>A p.P847Q | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56669709; called by muse, mutect2
- DCDC1 | c.4277G>T p.G1426V (on ENST00000597505 / NM_001367979.1; = p.G533V on NM_020869.3) | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100338583; called by muse, mutect2, varscan2
- DDR2 | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 64/419 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs754868982, COSV63370876; called by muse, mutect2, varscan2
- DDX60L | c.1634G>T p.R545L | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV52708842; called by muse, mutect2, varscan2
- DDX60L | c.910C>G p.Q304E | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs768701537; called by muse, mutect2, varscan2
- DISP3 | c.3022G>A p.G1008R | Missense Mutation (SNP) | VAF 53/401 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs778206374; called by muse, mutect2, varscan2
- DOCK4 | c.5242C>T p.P1748S | Missense Mutation (SNP) | VAF 50/544 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as rs1352829144; called by muse, mutect2
- EGFLAM | c.1912G>C p.E638Q | Missense Mutation (SNP) | VAF 12/356 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); catalogued as COSV59314042; called by muse, mutect2
- EIF2S2 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100895008, COSV66622136; called by muse, mutect2, varscan2
- ESPN | c.265C>A p.L89M | Missense Mutation (SNP) | VAF 113/779 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1435148906; called by muse, mutect2, varscan2
- EXPH5 | c.3766C>G p.L1256V | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99761292; called by muse, mutect2, varscan2
- FBXO33 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 80/744 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs751020412; called by muse, mutect2, varscan2
- FYB1 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 70/615 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs775145174, COSV60954228; called by muse, mutect2, varscan2
- GAD1 | c.595G>T p.G199C | Missense Mutation (SNP) | VAF 77/554 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs78714733; called by muse, mutect2, varscan2
- GRM3 | c.1513C>A p.P505T | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64470255; called by muse, mutect2, varscan2
- H3-2 | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 72/355 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as rs782665905; called by muse, mutect2, varscan2
- HCN1 | c.2468C>A p.P823H | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV100298017, COSV57531605; called by muse, mutect2
- IGHE | c.992C>A p.T331K | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.93); catalogued as rs368118853; called by muse, mutect2, varscan2
- IRF6 | c.717G>C p.Q239H | Missense Mutation (SNP) | VAF 29/234 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.671); catalogued as COSV65419446; called by muse, mutect2, varscan2
- KIF23 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.304); catalogued as rs756821487; called by muse, mutect2, varscan2
- KRTAP4-2 | c.134G>T p.C45F | Missense Mutation (SNP) | VAF 113/643 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1414496208; called by muse, mutect2, varscan2
- LAMA4 | c.1673C>T p.A558V (on ENST00000230538 / NM_001105206.3; = p.A551V on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/335 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs137893207, COSV57896467, COSV57897455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LARS1 | c.2212G>A p.G738R (on ENST00000394434 / NM_020117.11; = p.G711R on NM_016460.3) | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99198560; called by muse, mutect2
- LEPR | c.3104C>T p.A1035V | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.33); catalogued as COSV62747606; called by muse, mutect2, varscan2
- LHFPL3 | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 29/398 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); catalogued as rs1195823370; called by muse, mutect2
- LRRC19 | c.578C>T p.T193I | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs1440134374; called by muse, varscan2
- LRRC49 | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV53013900; called by muse, mutect2
- MAGEB1 | c.961G>T p.V321F | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV66775490; called by muse, mutect2, varscan2
- MRM1 | c.393G>A p.W131* | Nonsense Mutation (SNP) | VAF 35/262 reads (13%) | catalogued as rs376476399; called by muse, mutect2, varscan2
- MSL3 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs191141351, COSV56493475; called by muse, mutect2, varscan2
- MTCL1 | c.4223C>T p.P1408L (on ENST00000306329 / NM_001378206.1; = p.P1089L on NM_015210.4) | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as rs145193610; called by muse, mutect2, varscan2
- MTRR | c.1910C>G p.S637* (on ENST00000264668; = p.S610* on NM_002454.3 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 36/384 reads (9%) | catalogued as COSV52944113; called by muse, mutect2
- MUC5B | c.5497G>A p.E1833K | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as rs753352418; called by muse, mutect2, varscan2
- MYO18B | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.234); catalogued as rs762886452; called by muse, mutect2
- MYO1H | c.1818C>A p.D606E | Missense Mutation (SNP) | VAF 41/312 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs755386221; called by muse, mutect2, varscan2
- NFKBIE | c.1358C>T p.S453L (on ENST00000275015; = p.S314L on NM_004556.3) | Missense Mutation (SNP) | VAF 65/419 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.388); catalogued as rs753094918; called by muse, mutect2, varscan2
- NPAS3 | c.712C>T p.Q238* (on ENST00000356141 / NM_001164749.2; = p.Q206* on NM_022123.3) | Nonsense Mutation (SNP) | VAF 16/86 reads (19%) | catalogued as COSV100386586; called by muse, mutect2, varscan2
- NRROS | c.1522G>T p.D508Y | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100145451; called by muse, mutect2
- NYAP2 | c.1696C>G p.H566D | Missense Mutation (SNP) | VAF 54/502 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs1380210056; called by muse, mutect2
- OPN5 | c.537C>A p.F179L | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55245155; called by muse, mutect2, varscan2
- OR10H3 | c.232A>G p.I78V | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs748595747; called by muse, mutect2, varscan2
- OR14A16 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs893606356, COSV100713715, COSV62926846; called by muse, mutect2, varscan2
- OR2L3 | c.75C>A p.F25L | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV63455422; called by muse, mutect2, varscan2
- OR2L3 | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV63454418; called by muse, mutect2, varscan2
- OR2M3 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 43/427 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as rs868168605, COSV71759195; called by muse, mutect2, varscan2
- OR2M5 | c.591G>T p.K197N | Missense Mutation (SNP) | VAF 51/396 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV63547034; called by muse, mutect2, varscan2
- OR51E1 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs1302310867, COSV101211474; called by muse, mutect2, varscan2
- OR56A5 | c.531C>G p.I177M | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60828084; called by muse, mutect2, varscan2
- OR5M11 | c.485C>A p.T162N | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs766544986; called by muse, mutect2, varscan2
- PARD6B | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 49/380 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65405222; called by muse, mutect2, varscan2
- PCDHGA4 | c.2457C>G p.S819R | Missense Mutation (SNP) | VAF 47/483 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.041); catalogued as rs373329089; called by muse, mutect2, varscan2
- PDCL3 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 9/69 reads (13%) | catalogued as COSV51809826; called by muse, mutect2
- PDIA5 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 27/242 reads (11%) | catalogued as rs942285555, COSV60252939; called by muse, mutect2, varscan2
- PITX2 | c.349G>C p.E117Q (on ENST00000354925 / NM_001204397.1; = p.E124Q on NM_000325.6) | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60740015, COSV60741296; called by muse, mutect2, varscan2
- PKP4 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.699); catalogued as rs776377978, COSV67676997, COSV67677234; called by muse, mutect2, varscan2
- PLCZ1 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 17/309 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as rs1308051972, COSV56855967; called by muse, mutect2
- PLEC | c.2953G>A p.E985K (on ENST00000322810 / NM_201380.4; = p.E875K on NM_000445.5) | Missense Mutation (SNP) | VAF 65/599 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs781977174; ClinVar: uncertain significance; called by muse, mutect2
- PNKP | c.1175T>G p.V392G | Missense Mutation (SNP) | VAF 69/542 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as rs1228430540; called by muse, mutect2, varscan2
- POLL | c.892-1G>T p.X298_splice | Splice Site (SNP) | VAF 22/187 reads (12%) | catalogued as COSV54574870; called by muse, mutect2, varscan2
- POLQ | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs780704056; called by muse, mutect2, varscan2
- POT1 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 128/488 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as COSV62933813; called by muse, varscan2
- PRPF4B | c.464G>A p.R155K | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs777324004; called by muse, mutect2, varscan2
- PXDNL | c.3138C>A p.N1046K | Missense Mutation (SNP) | VAF 58/626 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104422437; called by muse, mutect2
- RAD51AP2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV101208390; called by muse, mutect2
- RIMS2 | c.1523G>T p.R508L (on ENST00000666250 / NM_001348490.2; = p.R316L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/403 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV51669990; called by muse, mutect2
- RPH3A | c.208G>C p.E70Q (on ENST00000389385 / NM_001143854.2; = p.E66Q on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.54); catalogued as COSV66990489; called by muse, mutect2
- RTN1 | c.1448G>C p.R483P | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs867180903, COSV99954276; called by muse, mutect2, varscan2
- SDHAF4 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 23/193 reads (12%) | catalogued as COSV65085367; called by muse, mutect2, varscan2
- SETD1A | c.3227C>T p.S1076L | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.039); catalogued as rs765486074; called by muse, varscan2
- SLC13A3 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as COSV51719459; called by muse, mutect2
- SLC13A4 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.14); catalogued as COSV62459983; called by muse, mutect2, varscan2
- SLCO5A1 | c.1623-2A>T p.X541_splice | Splice Site (SNP) | VAF 8/75 reads (11%) | catalogued as rs764237043; called by muse, mutect2
- SMAD4 | c.1116G>T p.R372S | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100748374; called by muse, mutect2, varscan2
- SNTG1 | c.1383G>T p.Q461H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.459); catalogued as COSV52424658, COSV52442598; called by muse, mutect2, varscan2
- SOAT2 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 32/354 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141707834; called by muse, mutect2
- SP140 | c.1247G>T p.S416I | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV100613987; called by mutect2, varscan2
- SPANXN2 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 93/469 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.426); catalogued as rs782731457, COSV65128497; called by muse, varscan2
- SPRING1 | c.110A>T p.Q37L | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as rs1282206667; called by muse, mutect2, varscan2
- SPTA1 | c.2242G>T p.D748Y | Missense Mutation (SNP) | VAF 41/327 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.218); catalogued as COSV63752030; called by muse, mutect2, varscan2
- STK3 | c.948G>T p.S316= | Splice Region (SNP) | VAF 17/204 reads (8%) | catalogued as rs774171930, COSV69226371; called by muse, mutect2
- SULF2 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59073825; called by muse, mutect2, varscan2
- TBC1D21 | c.685G>T p.G229C | Missense Mutation (SNP) | VAF 47/339 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs754519110, COSV55995736, COSV55996787; called by muse, mutect2, varscan2
- TFAP4 | c.911G>T p.C304F | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as rs768649035; called by muse, mutect2, varscan2
- TMC3 | c.2261C>A p.T754N | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as rs1033865073; called by muse, mutect2, varscan2
- TMTC4 | c.2192G>A p.R731K (on ENST00000376234 / NM_001350577.2; = p.R750K on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as COSV60892317; called by muse, mutect2, varscan2
- TRAT1 | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV55468946, COSV55469125; called by muse, mutect2
- TRPM6 | c.1732G>T p.E578* | Nonsense Mutation (SNP) | VAF 23/197 reads (12%) | catalogued as COSV62503016; called by muse, mutect2, varscan2
- TTN | c.24814G>C p.E8272Q (on ENST00000591111; = p.E7345Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/271 reads (11%) | PolyPhen benign (0.007); catalogued as COSV60072415; called by muse, mutect2, varscan2
- UNC13A | c.4215G>C p.L1405F | Missense Mutation (SNP) | VAF 23/265 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1568505908, COSV53187069; called by muse, mutect2
- UNC5D | c.2251C>T p.Q751* | Nonsense Mutation (SNP) | VAF 18/213 reads (8%) | catalogued as COSV99778092; called by muse, mutect2
- VCAN | c.2135T>C p.F712S | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs1394163521; called by muse, mutect2, varscan2
- VN1R4 | c.687C>G p.N229K | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs760166101; called by muse, mutect2, varscan2
- WNT1 | c.272G>T p.R91L | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV53296044, COSV53296088; called by muse, mutect2
- WNT7A | c.535C>G p.L179V | Missense Mutation (SNP) | VAF 30/315 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs758056637, COSV53198752; called by muse, mutect2
- XRCC3 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 56/454 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.034); catalogued as rs1014813913; called by muse, mutect2, varscan2
- ZNF217 | c.707A>G p.K236R | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs1324280122; called by muse, mutect2, varscan2
- ZNF728 | c.800G>T p.R267L | Missense Mutation (SNP) | VAF 52/382 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.035); catalogued as COSV74099300, COSV74099462; called by muse, mutect2, varscan2
- ZSCAN25 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 36/416 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs1314697023, COSV99500799; called by muse, mutect2
- ABCA13 | c.13095-1G>T p.X4365_splice | Splice Site (SNP) | VAF 21/119 reads (18%) | called by muse, mutect2
- ACOXL | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 34/310 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- ADGRV1 | c.9288G>C p.E3096D | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.824); called by muse, mutect2
- ADHFE1 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ADPRH | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- ADPRHL1 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 77/351 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- AICDA | c.463C>A p.H155N | Missense Mutation (SNP) | VAF 16/313 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- AKAP3 | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 17/261 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.34); called by muse, mutect2
- AKAP6 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- ALK | c.2152G>T p.G718C | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AMER2 | c.1566G>T p.E522D | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- ANK2 | c.8317G>T p.D2773Y | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- ANKRD17 | c.5700C>A p.F1900L | Missense Mutation (SNP) | VAF 106/957 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ANKRD31 | c.2149G>T p.V717F | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ANLN | c.1582G>C p.E528Q | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- AOC1 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.88); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARFGAP2 | c.245T>C p.V82A | Missense Mutation (SNP) | VAF 48/403 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- ARID1B | c.6036G>C p.L2012F | Missense Mutation (SNP) | VAF 36/269 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- ARL9 | c.544G>A p.E182K (on ENST00000640821 / NM_001363794.2; = p.E40K on NM_206919.2) | Missense Mutation (SNP) | VAF 56/350 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ARTN | c.484G>A p.D162N (on ENST00000372354; = p.D170N on NM_057090.2) | Missense Mutation (SNP) | VAF 56/443 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATG9B | c.748_749del p.T250Qfs*23 | Frame Shift Del (DEL) | VAF 146/544 reads (27%) | called by mutect2, pindel, varscan2
- BCAT2 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- BCLAF1 | c.2479C>G p.Q827E | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.764); called by muse, mutect2
- BCORL1 | c.4238C>G p.S1413* | Nonsense Mutation (SNP) | VAF 51/231 reads (22%) | called by muse, mutect2, varscan2
- BFSP2 | c.202G>T p.G68C | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- BIN2 | c.1496C>A p.P499H | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- BIRC6 | c.11156dup p.L3719Ffs*12 | Frame Shift Ins (INS) | VAF 33/301 reads (11%) | called by mutect2, pindel, varscan2
- C10orf71 | c.666del p.K223Rfs*90 | Frame Shift Del (DEL) | VAF 40/407 reads (10%) | called by mutect2, pindel, varscan2
- C11orf95 | c.1256A>T p.Q419L | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.547); called by muse, mutect2
- C16orf78 | c.295G>C p.D99H | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- C20orf203 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.514); called by muse, mutect2
- CACNG8 | c.440C>A p.A147E | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- CAPN7 | c.1154G>C p.G385A | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- CASP8AP2 | c.4367T>G p.L1456R | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBL | c.2360G>T p.R787L | Missense Mutation (SNP) | VAF 55/457 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- CCK | c.172C>A p.L58M | Missense Mutation (SNP) | VAF 37/370 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CCNG1 | c.392T>A p.V131D | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- CCNG1 | c.707G>C p.R236T | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCNQ | c.699del p.I233Mfs*113 | Frame Shift Del (DEL) | VAF 38/191 reads (20%) | called by mutect2, pindel, varscan2
- CD109 | c.3544C>G p.Q1182E | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- CDH18 | c.2156G>T p.R719I | Missense Mutation (SNP) | VAF 23/318 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- CEACAM20 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 44/390 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- CEP250 | c.3058G>T p.V1020L | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CILP | c.2315G>T p.G772V | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLASP2 | c.1237G>T p.V413L | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.196); called by muse, mutect2
- CNTNAP2 | c.472T>C p.Y158H | Missense Mutation (SNP) | VAF 172/532 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- COL28A1 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 19/281 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2
- COL5A2 | c.1770+1G>T p.X590_splice | Splice Site (SNP) | VAF 21/258 reads (8%) | called by muse, mutect2
- COPB2 | c.277C>T p.H93Y | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- CSMD3 | c.7633G>C p.V2545L (on ENST00000297405 / NM_001363185.1; = p.V2441L on NM_052900.3) | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CSMD3 | c.7015G>T p.V2339L (on ENST00000297405 / NM_001363185.1; = p.V2235L on NM_052900.3) | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2
- CYP4A22 | c.198C>G p.F66L | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.011); called by muse, mutect2
- DDX55 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DHRS11 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 47/504 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.069); called by muse, mutect2
- DLGAP2 | c.2216C>A p.T739K | Missense Mutation (SNP) | VAF 31/245 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DOCK7 | c.4661G>C p.C1554S (on ENST00000635253 / NM_001367561.1; = p.C1523S on NM_033407.3) | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DST | c.15892C>A p.Q5298K (on ENST00000361203 / NM_001374722.1; = p.Q2886K on NM_015548.5) | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- DYNC1H1 | c.10792G>C p.E3598Q | Missense Mutation (SNP) | VAF 57/486 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- EGLN3 | c.624G>T p.M208I | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EML6 | c.3895G>T p.A1299S | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- EOGT | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 53/462 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- EPB41L4B | c.1623G>T p.K541N | Missense Mutation (SNP) | VAF 36/288 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, mutect2
- EPB41L4B | c.632-2A>T p.X211_splice | Splice Site (SNP) | VAF 17/115 reads (15%) | called by muse, mutect2, varscan2
- EPC1 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 47/303 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- EPHA10 | c.2730del p.K911Sfs*4 | Frame Shift Del (DEL) | VAF 28/248 reads (11%) | called by mutect2, pindel
- EPHB2 | c.1155G>C p.Q385H | Missense Mutation (SNP) | VAF 26/263 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- EXOSC9 | c.798G>T p.L266F | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- F5 | c.1550C>A p.S517Y | Missense Mutation (SNP) | VAF 42/306 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM90A26 | c.1261G>T p.G421* | Nonsense Mutation (SNP) | VAF 114/447 reads (26%) | called by muse, mutect2, varscan2
- FAT3 | c.8158G>C p.D2720H | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FER1L6 | c.1580C>A p.S527* | Nonsense Mutation (SNP) | VAF 22/281 reads (8%) | called by muse, mutect2
- FETUB | c.1123G>T p.A375S | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FIGN | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 39/238 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- FMO4 | c.1504G>T p.V502F | Missense Mutation (SNP) | VAF 44/466 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by muse, mutect2
- FSIP2 | c.11053G>A p.G3685S | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSTL4 | c.2063del p.V688Efs*14 | Frame Shift Del (DEL) | VAF 23/174 reads (13%) | called by mutect2, pindel, varscan2
- GABRG1 | c.624C>T p.S208= | Splice Region (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- GJB4 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 53/430 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- GOLM2 | c.136_145del p.V46Cfs*78 | Frame Shift Del (DEL) | VAF 57/635 reads (9%) | called by mutect2, pindel*
- GRAMD1B | c.2033G>T p.W678L | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GREB1 | c.1561T>A p.C521S | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.647); called by muse, mutect2
- GRIA1 | c.1614G>T p.E538D | Missense Mutation (SNP) | VAF 41/333 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- GRM6 | c.2249C>G p.S750C | Missense Mutation (SNP) | VAF 49/492 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- HAUS5 | c.284A>T p.D95V | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- HECTD3 | c.583C>G p.Q195E | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.011); called by muse, mutect2
- HERC2 | c.8371G>T p.V2791L | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); called by muse, mutect2
- HTT | c.5416G>T p.D1806Y | Missense Mutation (SNP) | VAF 58/502 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- HYDIN | c.3675T>A p.S1225R | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2
- IER5 | c.917A>G p.Q306R | Missense Mutation (SNP) | VAF 84/766 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- IGKV2D-24 | c.261C>A p.F87L | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IL6R | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 17/355 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.692); called by muse, mutect2
- ITGA2B | c.532C>G p.R178G | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNB2 | c.1665C>A p.H555Q | Missense Mutation (SNP) | VAF 35/279 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- KCNG1 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNG4 | c.1517A>T p.D506V | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KCNN4 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 57/400 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- KCTD16 | c.384G>T p.K128N | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- KERA | c.653T>A p.L218* | Nonsense Mutation (SNP) | VAF 24/338 reads (7%) | called by muse, mutect2
- KIAA0825 | c.429G>C p.R143S | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2
- KLHDC4 | c.388G>T p.G130C | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- KLHDC7A | c.233G>A p.R78K | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRT27 | c.1251A>T p.K417N | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); called by muse, mutect2
- KYNU | c.829T>A p.Y277N | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA2 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT tolerated (0.87); PolyPhen benign (0.015); called by muse, mutect2
- LAMP5 | c.667C>A p.H223N | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- LCORL | c.1291G>T p.G431C | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRP1B | c.12940del p.E4314Nfs*17 | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | called by mutect2, varscan2
- MAGEA12 | c.527A>G p.Y176C | Missense Mutation (SNP) | VAF 68/317 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEC1 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 48/245 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.136); called by mutect2, varscan2
- MAN1A2 | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MAPRE1 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MARCHF1 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 37/281 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MARCHF6 | c.14A>G p.E5G | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MEGF8 | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 31/191 reads (16%) | called by muse, mutect2, varscan2
- MMEL1 | c.2123A>C p.D708A | Missense Mutation (SNP) | VAF 15/249 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2
- MMS22L | c.2680G>T p.A894S | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.453); called by muse, mutect2
- MN1 | c.3391G>T p.G1131C | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- MTF1 | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MTMR10 | c.880C>T p.L294F | Missense Mutation (SNP) | VAF 47/416 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC17 | c.1655C>G p.S552C | Missense Mutation (SNP) | VAF 89/565 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- MUC19 | c.1280G>A p.G427E | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MVD | c.233G>C p.R78P | Missense Mutation (SNP) | VAF 43/318 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by mutect2, varscan2
- MYO1G | c.13G>T p.E5* | Nonsense Mutation (SNP) | VAF 29/259 reads (11%) | called by muse, mutect2, varscan2
- MYOG | c.159G>T p.K53N | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2
- NAP1L4 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 6/128 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); called by muse, mutect2
- NAV3 | c.2380G>T p.G794* | Nonsense Mutation (SNP) | VAF 56/255 reads (22%) | called by muse, mutect2, varscan2
- NCAPD3 | c.3796G>C p.E1266Q | Missense Mutation (SNP) | VAF 31/366 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.147); called by muse, mutect2
- NEDD4 | c.3832G>A p.E1278K (on ENST00000508342 / NM_001284338.1; = p.E859K on NM_006154.4) | Missense Mutation (SNP) | VAF 26/321 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); called by muse, mutect2
- NEK10 | c.1406T>C p.I469T | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NFE2L1 | c.1010A>G p.Y337C | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.864); called by muse, varscan2
- NLRP11 | c.2914A>T p.R972* | Nonsense Mutation (SNP) | VAF 28/223 reads (13%) | called by muse, mutect2, varscan2
- NT5DC3 | c.496C>G p.H166D | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); called by muse, mutect2
- OR11H6 | c.210C>G p.D70E | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- OR1L3 | c.264G>C p.E88D | Missense Mutation (SNP) | VAF 30/277 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- OR2D3 | c.17T>G p.L6W | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR52L1 | c.410C>G p.A137G | Missense Mutation (SNP) | VAF 44/474 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2
- OR5J2 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- OR5M8 | c.300T>G p.C100W | Missense Mutation (SNP) | VAF 37/310 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR9Q1 | c.153G>T p.M51I | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2
- OVCH1 | c.2708C>T p.S903L | Missense Mutation (SNP) | VAF 41/293 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- OXR1 | c.1577C>T p.S526L (on ENST00000442977 / NM_001198532.1; = p.S525L on NM_018002.3) | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PADI6 | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 20/272 reads (7%) | called by muse, mutect2
- PCDHAC2 | c.1477G>T p.A493S | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHB11 | c.2050G>T p.D684Y | Missense Mutation (SNP) | VAF 86/642 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PCDHB14 | c.1129G>T p.D377Y | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- PCDHB16 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- PCDHGA9 | c.357A>G p.I119M | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- PCF11 | c.2053G>T p.V685F | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); called by muse, mutect2
- PCLO | c.15026del p.G5009Efs*7 | Frame Shift Del (DEL) | VAF 13/99 reads (13%) | called by mutect2, pindel, varscan2
- PCSK1 | c.1679G>A p.G560E | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PDE10A | c.1325T>A p.M442K | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PDZD2 | c.5041G>A p.D1681N | Missense Mutation (SNP) | VAF 27/283 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- PDZRN4 | c.780A>C p.K260N | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); called by muse, mutect2
- PIK3CG | c.2458C>G p.P820A | Missense Mutation (SNP) | VAF 28/375 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2
- PIK3R4 | c.3760C>T p.P1254S | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLCE1 | c.4552G>T p.D1518Y | Missense Mutation (SNP) | VAF 44/394 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHA5 | c.2607G>C p.L869F | Missense Mutation (SNP) | VAF 9/217 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLEKHB2 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 6/134 reads (4%) | PolyPhen benign (0.003); called by muse, mutect2
- PLEKHH2 | c.1895C>T p.S632F | Missense Mutation (SNP) | VAF 34/316 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- PLXNB2 | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 30/337 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.58); called by muse, mutect2
- POTEC | c.482T>A p.L161H | Missense Mutation (SNP) | VAF 61/587 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP1R12A | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2
- PPP1R7 | c.532A>G p.K178E | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2
- PPP4R3B | c.753_758del p.P253_I254del | In Frame Del (DEL) | VAF 55/479 reads (11%) | called by mutect2, pindel, varscan2
- PPP4R3C | c.2025A>C p.E675D | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- PRSS45P | c.222G>T p.W74C | Missense Mutation (SNP) | VAF 51/477 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- PSME4 | c.4945-1G>A p.X1649_splice | Splice Site (SNP) | VAF 30/330 reads (9%) | called by muse, mutect2
- PTPRZ1 | c.6179-1G>A p.X2060_splice | Splice Site (SNP) | VAF 98/368 reads (27%) | called by muse, mutect2, varscan2
- PZP | c.3369T>A p.T1123= | Splice Region (SNP) | VAF 50/196 reads (26%) | called by muse, mutect2, varscan2
- RAD18 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.351); called by muse, mutect2
- RALBP1 | c.1553G>A p.R518K | Missense Mutation (SNP) | VAF 34/263 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- RANBP10 | c.1544G>T p.G515V | Missense Mutation (SNP) | VAF 50/532 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAPGEF2 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 16/137 reads (12%) | called by muse, mutect2, varscan2
- RASSF5 | c.397G>T p.G133C | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2
- RFPL4A | c.698G>T p.S233I | Missense Mutation (SNP) | VAF 84/1584 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); called by muse, mutect2
- RFPL4AL1 | c.698G>T p.S233I | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- RGPD3 | c.5233G>A p.E1745K | Missense Mutation (SNP) | VAF 96/744 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- RHOT2 | c.1511G>T p.C504F | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ROBO2 | c.2462G>T p.G821V | Missense Mutation (SNP) | VAF 40/288 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPS6KB1 | c.1216C>G p.Q406E | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SAMD4A | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 43/355 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SCAMP3 | c.144+5G>C | Splice Region (SNP) | VAF 28/255 reads (11%) | called by muse, mutect2, varscan2
- SEC23B | c.1444C>T p.Q482* | Nonsense Mutation (SNP) | VAF 75/686 reads (11%) | called by muse, mutect2, varscan2
- SERPINB7 | c.401A>T p.H134L | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SFTPB | c.352_354del p.D118del | In Frame Del (DEL) | VAF 24/230 reads (10%) | called by pindel, varscan2
- SHANK1 | c.5414G>A p.G1805E | Missense Mutation (SNP) | VAF 59/316 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- SHISA9 | c.730C>A p.L244M | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SI | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC23A3 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 48/473 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SLC25A19 | c.559_560delinsT p.P187Sfs*13 | Frame Shift Del (DEL) | VAF 53/395 reads (13%) | called by pindel, varscan2*
- SLC25A48 | c.539_540insT p.A181Gfs*24 (on ENST00000650267; = p.A127Gfs*24 on NM_001349335.1 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 28/247 reads (11%) | called by mutect2, pindel, varscan2
- SLC28A2 | c.527C>G p.P176R | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SLC8A1 | c.2705T>C p.V902A | Missense Mutation (SNP) | VAF 38/319 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLIT2 | c.988G>T p.D330Y | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLITRK5 | c.781del p.D261Mfs*2 | Frame Shift Del (DEL) | VAF 24/282 reads (9%) | called by mutect2, pindel
- SMC1A | c.3694G>A p.E1232K | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SPATA31D3 | c.2318G>T p.S773I | Missense Mutation (SNP) | VAF 58/554 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- SPEN | c.6712C>A p.P2238T | Missense Mutation (SNP) | VAF 42/368 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPRR1A | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 31/380 reads (8%) | called by muse, mutect2
- STARD8 | c.2653G>C p.A885P | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- STAU2 | c.1015_1029+3del p.X339_splice (on ENST00000524300 / NM_001164380.2; = p.X307_splice on NM_014393.2) | Splice Site (DEL) | VAF 36/128 reads (28%) | called by mutect2, pindel, varscan2
- STK38L | c.1363A>C p.I455L | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2
- STX4 | c.662A>G p.H221R | Missense Mutation (SNP) | VAF 42/303 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SUPT5H | c.2497G>C p.E833Q | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- SVIL | c.2005G>C p.D669H | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); called by muse, mutect2
- TAF1 | c.4116C>G p.I1372M (on ENST00000373790 / NM_138923.4; = p.I1393M on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- TENM2 | c.1904T>G p.V635G (on ENST00000518659 / NM_001122679.2; = p.V403G on NM_001080428.3) | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- THBS2 | c.2950C>A p.Q984K | Missense Mutation (SNP) | VAF 27/265 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TLCD3A | c.299G>C p.R100T | Missense Mutation (SNP) | VAF 80/567 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TMEM222 | c.406A>C p.M136L | Missense Mutation (SNP) | VAF 42/303 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- TMTC1 | c.1295G>T p.C432F (on ENST00000539277 / NM_001193451.2; = p.C324F on NM_175861.3) | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- TNRC18 | c.739_740del p.A247Rfs*13 | Frame Shift Del (DEL) | VAF 21/169 reads (12%) | called by pindel, varscan2
- TRIM58 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 48/540 reads (9%) | called by muse, mutect2
- TSHZ3 | c.2693G>T p.W898L | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- TSHZ3 | c.2692T>C p.W898R | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- UBE3A | c.1905G>T p.M635I | Missense Mutation (SNP) | VAF 37/281 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- UNC80 | c.1909C>T p.H637Y | Missense Mutation (SNP) | VAF 35/276 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- USP6 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 71/508 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS13C | c.7369G>A p.D2457N (on ENST00000644861 / NM_020821.3; = p.D2414N on NM_017684.5) | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.028); called by muse, mutect2
- WDR88 | c.348G>T p.K116N | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- XPO1 | c.1845G>C p.L615F | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZFHX2 | c.4973G>T p.G1658V | Missense Mutation (SNP) | VAF 34/317 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ZFP36L1 | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- ZNF235 | c.239-3C>T | Splice Region (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- ZNF488 | c.913C>A p.P305T | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.197); called by muse, mutect2
- ZNF500 | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 26/227 reads (11%) | called by muse, mutect2, varscan2
- ZNF511 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 59/373 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- ZNF582 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 29/301 reads (10%) | SIFT tolerated (0.97); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZNF638 | c.4174C>G p.P1392A | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF816-ZNF321P | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZZZ3 | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 36/306 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCB4 | c.3102A>C p.I1034= | Silent (SNP) | VAF 39/312 reads (13%) | called by muse, mutect2, varscan2
- AGPS | c.735G>A p.L245= | Silent (SNP) | VAF 29/272 reads (11%) | catalogued as rs952911907, COSV51563073; called by muse, mutect2, varscan2
- AKR7L | c.93C>T p.V31= | Silent (SNP) | VAF 43/432 reads (10%) | called by muse, mutect2, varscan2
- APC | c.3678G>A p.K1226= | Silent (SNP) | VAF 23/182 reads (13%) | called by muse, mutect2, varscan2
- AQP1 | c.225C>T p.L75= | Silent (SNP) | VAF 77/567 reads (14%) | called by muse, mutect2, varscan2
- ASZ1 | c.90C>T p.L30= | Silent (SNP) | VAF 41/421 reads (10%) | catalogued as rs1049423144, COSV52911857, COSV99498362; called by muse, mutect2, varscan2
- ATP8A1 | c.1242G>T p.L414= | Silent (SNP) | VAF 18/230 reads (8%) | called by muse, mutect2
- BRSK1 | c.1113C>G p.P371= | Silent (SNP) | VAF 17/228 reads (7%) | called by muse, mutect2
- C1orf141 | c.1056T>A p.S352= | Silent (SNP) | VAF 69/486 reads (14%) | called by muse, mutect2, varscan2
- CACNA1G | c.6163C>A p.R2055= | Silent (SNP) | VAF 41/178 reads (23%) | catalogued as COSV100661926; called by muse, mutect2, varscan2
- CADM2 | c.1047A>T p.T349= (on ENST00000407528 / NM_001167674.2; = p.T351= on NM_153184.4) | Silent (SNP) | VAF 27/190 reads (14%) | called by muse, mutect2, varscan2
- CBWD5 | c.1035G>A p.V345= (on ENST00000382405 / NM_001330668.1; = p.V297= on NM_001024916.3) | Silent (SNP) | VAF 44/1028 reads (4%) | called by muse, mutect2
- CCDC174 | c.981G>T p.P327= | Silent (SNP) | VAF 25/233 reads (11%) | called by muse, mutect2
- CCRL2 | c.481C>T p.L161= | Silent (SNP) | VAF 27/184 reads (15%) | catalogued as COSV62193479; called by muse, mutect2, varscan2
- CD5L | c.708C>A p.V236= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as rs770986368, COSV63822198, COSV63823291; called by muse, mutect2, varscan2
- CDCP2 | c.873G>A p.P291= | Silent (SNP) | VAF 53/413 reads (13%) | catalogued as rs933399338; called by muse, mutect2, varscan2
- CHAT | c.729C>T p.L243= | Silent (SNP) | VAF 80/726 reads (11%) | called by muse, varscan2
- CLEC4C | c.108C>T p.F36= | Silent (SNP) | VAF 20/258 reads (8%) | catalogued as rs867157232; called by muse, mutect2
- CLIP1 | c.978G>A p.V326= | Silent (SNP) | VAF 27/241 reads (11%) | catalogued as rs751066705; called by muse, varscan2
- CLN3 | c.75C>A p.L25= | Silent (SNP) | VAF 52/528 reads (10%) | catalogued as COSV60492433; called by muse, mutect2
- CMAS | c.1146G>A p.K382= | Silent (SNP) | VAF 15/142 reads (11%) | catalogued as COSV57556132; called by muse, mutect2, varscan2
- COL18A1 | c.3700T>C p.L1234= (on ENST00000359759 / NM_130444.3; = p.L999= on NM_030582.4) | Silent (SNP) | VAF 47/357 reads (13%) | called by muse, mutect2, varscan2
- CORO2B | c.249C>A p.V83= | Silent (SNP) | VAF 33/290 reads (11%) | catalogued as COSV99963141, COSV99963222; called by muse, mutect2, varscan2
- CRPPA | c.45T>A p.G15= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs960627721; called by muse, mutect2, varscan2
- DNAJB12 | c.924G>A p.L308= (on ENST00000338820; = p.L274= on NM_017626.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 25/246 reads (10%) | called by muse, mutect2, varscan2
- DST | c.15891C>A p.L5297= (on ENST00000361203 / NM_001374722.1; = p.L2885= on NM_015548.5) | Silent (SNP) | VAF 23/125 reads (18%) | called by muse, mutect2, varscan2
- DVL1 | c.1026G>T p.T342= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs753965150; called by muse, mutect2, varscan2
- DYNC2I2 | c.879G>C p.G293= | Silent (SNP) | VAF 30/266 reads (11%) | called by muse, mutect2, varscan2
- ECM1 | c.621T>G p.G207= | Silent (SNP) | VAF 56/373 reads (15%) | called by muse, mutect2, varscan2
- EIF3F | c.1077G>T p.G359= | Silent (SNP) | VAF 13/106 reads (12%) | called by muse, mutect2, varscan2
- ERICH3 | c.3066C>T p.A1022= | Silent (SNP) | VAF 24/314 reads (8%) | catalogued as rs769814781, COSV100444549, COSV58620443; called by muse, mutect2
- FBH1 | c.1404G>A p.G468= (on ENST00000362091 / NM_178150.3; = p.G519= on NM_032807.4) | Silent (SNP) | VAF 18/118 reads (15%) | called by muse, mutect2
- FBN2 | c.7554G>A p.P2518= | Silent (SNP) | VAF 66/564 reads (12%) | catalogued as rs202192296, COSV52518105; called by muse, mutect2, varscan2
- FBN2 | c.2025C>T p.N675= | Silent (SNP) | VAF 56/436 reads (13%) | called by muse, mutect2, varscan2
- FOXL1 | c.730C>T p.L244= | Silent (SNP) | VAF 14/218 reads (6%) | called by muse, mutect2
- FRYL | c.6873G>A p.K2291= | Silent (SNP) | VAF 19/145 reads (13%) | catalogued as rs745329896; called by muse, mutect2, varscan2
- GCM2 | c.12C>A p.A4= | Silent (SNP) | VAF 72/509 reads (14%) | catalogued as COSV65275468; called by muse, mutect2, varscan2
- GIT2 | c.711G>A p.R237= | Silent (SNP) | VAF 29/272 reads (11%) | catalogued as rs767059062, COSV58080956; called by muse, mutect2
- GLTP | c.72C>G p.L24= | Silent (SNP) | VAF 36/511 reads (7%) | catalogued as COSV59172704; called by muse, mutect2
- GPR19 | c.378C>T p.F126= | Silent (SNP) | VAF 16/144 reads (11%) | called by muse, mutect2
- GRIK2 | c.2121C>A p.A707= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs200287424; called by muse, mutect2, varscan2
- GSE1 | c.1510C>T p.L504= | Silent (SNP) | VAF 14/179 reads (8%) | called by muse, mutect2
- GUSB | c.1446G>A p.V482= | Silent (SNP) | VAF 71/584 reads (12%) | called by muse, mutect2, varscan2
- HMCN2 | c.11253C>T p.A3751= | Silent (SNP) | VAF 34/358 reads (9%) | catalogued as rs907133400; called by muse, mutect2
- ICE1 | c.2946G>A p.Q982= | Silent (SNP) | VAF 13/117 reads (11%) | called by muse, mutect2, varscan2
- IER2 | c.30C>T p.I10= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs779539967; called by muse, mutect2, varscan2
- IQSEC1 | c.1845C>T p.I615= | Silent (SNP) | VAF 12/132 reads (9%) | called by muse, mutect2
- ITGAD | c.2448C>T p.V816= | Silent (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- ITIH6 | c.264C>A p.I88= | Silent (SNP) | VAF 23/101 reads (23%) | called by muse, mutect2, varscan2
- KANSL2 | c.906C>T p.C302= | Silent (SNP) | VAF 38/248 reads (15%) | called by muse, mutect2, varscan2
- KMT2D | c.11391G>T p.G3797= | Silent (SNP) | VAF 50/197 reads (25%) | called by muse, mutect2, varscan2
- KRT32 | c.123C>T p.C41= | Silent (SNP) | VAF 74/678 reads (11%) | called by muse, mutect2, varscan2
- LAMP2 | c.654A>G p.P218= | Silent (SNP) | VAF 24/138 reads (17%) | called by muse, mutect2, varscan2
- LCK | c.456C>T p.L152= | Silent (SNP) | VAF 32/315 reads (10%) | called by muse, mutect2
- LCP1 | c.1611C>T p.S537= | Silent (SNP) | VAF 26/184 reads (14%) | called by muse, mutect2
- LIG1 | c.555C>T p.P185= | Silent (SNP) | VAF 32/237 reads (14%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.1195C>A p.R399= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as rs771944726, COSV63042957, COSV63045333; called by muse, mutect2, varscan2
- LTBP1 | c.246G>A p.E82= | Silent (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2, varscan2
- MACF1 | c.2376C>T p.F792= | Silent (SNP) | VAF 20/123 reads (16%) | called by muse, mutect2, varscan2
- MC5R | c.36C>T p.L12= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs751128056; called by muse, mutect2, varscan2
- MCMDC2 | c.1432C>T p.L478= | Silent (SNP) | VAF 28/93 reads (30%) | called by muse, mutect2, varscan2
- MDGA2 | c.1191G>T p.V397= (on ENST00000399232 / NM_001113498.2; = p.V99= on NM_182830.4) | Silent (SNP) | VAF 17/136 reads (13%) | called by muse, varscan2
- MED13L | c.3534C>G p.L1178= | Silent (SNP) | VAF 56/816 reads (7%) | catalogued as rs781378515, COSV56126269; called by muse, mutect2
- MICAL3 | c.1725G>T p.V575= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as COSV52894566; called by muse, mutect2
- MMP9 | c.1245G>A p.P415= | Silent (SNP) | VAF 71/571 reads (12%) | catalogued as rs1238988235; called by muse, mutect2, varscan2
- MROH5 | c.1407G>C p.R469= | Silent (SNP) | VAF 31/319 reads (10%) | called by muse, mutect2, varscan2
- MYH4 | c.567G>A p.T189= | Silent (SNP) | VAF 37/243 reads (15%) | catalogued as rs777645610, COSV55127939; called by muse, mutect2, varscan2
- MYO10 | c.1167C>T p.L389= | Silent (SNP) | VAF 28/175 reads (16%) | called by muse, mutect2, varscan2
- NCOR2 | c.4287G>T p.P1429= | Silent (SNP) | VAF 55/261 reads (21%) | called by muse, mutect2, varscan2
- NT5C1B | c.319C>T p.L107= (on ENST00000359846 / NM_001199086.2; = p.L47= on NM_033253.4) | Silent (SNP) | VAF 22/167 reads (13%) | catalogued as rs201679289; called by muse, mutect2, varscan2
- OR10K2 | c.246G>T p.L82= | Silent (SNP) | VAF 48/389 reads (12%) | called by muse, mutect2, varscan2
- OR51D1 | c.789C>T p.V263= | Silent (SNP) | VAF 36/392 reads (9%) | catalogued as COSV62913846; called by muse, mutect2
- OR5T3 | c.669C>A p.I223= | Silent (SNP) | VAF 37/253 reads (15%) | catalogued as rs866879324; called by muse, mutect2, varscan2
- OR8U1 | c.840G>C p.V280= | Silent (SNP) | VAF 28/233 reads (12%) | called by muse, mutect2, varscan2
- PATJ | c.4554A>G p.R1518= | Silent (SNP) | VAF 57/515 reads (11%) | called by muse, mutect2, varscan2
- PCDHGA6 | c.1143G>T p.L381= | Silent (SNP) | VAF 40/357 reads (11%) | called by muse, mutect2, varscan2
- PDE6C | c.384G>A p.V128= | Silent (SNP) | VAF 44/468 reads (9%) | catalogued as rs747289754; called by muse, mutect2
- PLAAT2 | c.183G>A p.K61= | Silent (SNP) | VAF 44/317 reads (14%) | called by muse, mutect2, varscan2
- PLD2 | c.1764G>T p.T588= | Silent (SNP) | VAF 35/305 reads (11%) | catalogued as COSV99562744; called by muse, mutect2, varscan2
- POM121L12 | c.261C>A p.A87= | Silent (SNP) | VAF 33/317 reads (10%) | called by muse, mutect2, varscan2
- PRKDC | c.2049C>T p.F683= | Silent (SNP) | VAF 16/135 reads (12%) | catalogued as rs774140812, COSV58055615; called by muse, mutect2, varscan2
- PSG6 | c.198C>A p.I66= | Silent (SNP) | VAF 59/553 reads (11%) | catalogued as COSV51838801; called by muse, mutect2, varscan2
- RCC1L | c.981C>T p.P327= | Silent (SNP) | VAF 86/699 reads (12%) | catalogued as rs1188892280; called by muse, mutect2, varscan2
- RECQL | c.351T>A p.G117= | Silent (SNP) | VAF 44/211 reads (21%) | called by muse, mutect2, varscan2
- RESF1 | c.2271A>G p.E757= | Silent (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- RNF113B | c.462G>A p.L154= | Silent (SNP) | VAF 30/270 reads (11%) | catalogued as rs1206045976; called by muse, mutect2, varscan2
- RYBP | c.393T>C p.N131= | Silent (SNP) | VAF 34/250 reads (14%) | catalogued as rs753947554; called by muse, mutect2, varscan2
- SEMA6D | c.507T>C p.D169= | Silent (SNP) | VAF 18/176 reads (10%) | called by muse, mutect2, varscan2
- SHPRH | c.3333T>C p.N1111= (on ENST00000275233 / NM_001042683.3; = p.N1120= on NM_173082.3) | Silent (SNP) | VAF 22/228 reads (10%) | called by muse, mutect2
- SIGLEC10 | c.525C>A p.P175= | Silent (SNP) | VAF 28/246 reads (11%) | called by muse, mutect2, varscan2
- SLC15A5 | c.567G>A p.T189= | Silent (SNP) | VAF 41/294 reads (14%) | catalogued as rs985823210; called by muse, mutect2
- SLC25A13 | c.549C>T p.F183= | Silent (SNP) | VAF 29/281 reads (10%) | catalogued as COSV55713526, COSV55713646; called by muse, mutect2, varscan2
- SLIT3 | c.3450C>A p.A1150= | Silent (SNP) | VAF 34/210 reads (16%) | called by muse, mutect2, varscan2
- SNX29 | c.1512G>T p.A504= | Silent (SNP) | VAF 17/166 reads (10%) | catalogued as rs367917590; called by muse, mutect2, varscan2
- SORL1 | c.4866G>A p.T1622= | Silent (SNP) | VAF 10/142 reads (7%) | catalogued as rs183510875; called by muse, mutect2
- SPATA31A3 | c.765T>A p.S255= | Silent (SNP) | VAF 23/206 reads (11%) | called by mutect2, varscan2
- SPTBN4 | c.3111C>G p.R1037= | Silent (SNP) | VAF 34/266 reads (13%) | called by muse, mutect2, varscan2
- TENM3 | c.6532C>A p.R2178= | Silent (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
- TEP1 | c.6720A>T p.P2240= | Silent (SNP) | VAF 31/273 reads (11%) | called by muse, mutect2, varscan2
- TMC2 | c.1542G>T p.L514= | Silent (SNP) | VAF 36/231 reads (16%) | catalogued as COSV62653606; called by muse, mutect2, varscan2
- TMED5 | c.111C>A p.T37= | Silent (SNP) | VAF 31/287 reads (11%) | catalogued as COSV58147101; called by muse, mutect2, varscan2
- TMEM185A | c.342G>T p.L114= | Silent (SNP) | VAF 67/265 reads (25%) | catalogued as COSV104394531; called by muse, mutect2, varscan2
- TNIK | c.483G>A p.L161= | Silent (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- TNRC18 | c.7203C>T p.P2401= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as rs375864857; called by muse, mutect2, varscan2
- TPD52L3 | c.270G>A p.V90= | Silent (SNP) | VAF 70/482 reads (15%) | catalogued as COSV58828813; called by muse, mutect2, varscan2
- TSNARE1 | c.450G>T p.T150= | Silent (SNP) | VAF 30/157 reads (19%) | catalogued as COSV100210058, COSV56185348; called by muse, mutect2, varscan2
- UNC5C | c.2274G>A p.L758= | Silent (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- WDFY4 | c.2275C>A p.R759= | Silent (SNP) | VAF 26/206 reads (13%) | catalogued as COSV57436245; called by muse, mutect2, varscan2
- WDR36 | c.1986G>A p.L662= | Silent (SNP) | VAF 49/493 reads (10%) | catalogued as rs201719432; called by muse, mutect2
- WDR45B | c.270G>A p.K90= | Silent (SNP) | VAF 47/366 reads (13%) | catalogued as COSV66408532; called by muse, varscan2
- WWC1 | c.1686C>T p.L562= | Silent (SNP) | VAF 37/278 reads (13%) | catalogued as COSV54653807; called by muse, mutect2, varscan2
- XIRP2 | c.2838G>A p.K946= (on ENST00000628543; = p.K1121= on NM_152381.6) | Silent (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- XRCC2 | c.33G>A p.G11= | Silent (SNP) | VAF 121/631 reads (19%) | catalogued as rs781763823; called by muse, mutect2, varscan2
- ZFP57 | c.663C>T p.H221= | Silent (SNP) | VAF 42/239 reads (18%) | called by muse, mutect2, varscan2
- ZNF229 | c.900G>A p.E300= | Silent (SNP) | VAF 20/147 reads (14%) | called by muse, mutect2, varscan2
- ZNF280A | c.1095C>T p.V365= | Silent (SNP) | VAF 35/329 reads (11%) | catalogued as COSV57480763; called by muse, mutect2, varscan2
- ZNF423 | c.1218G>T p.R406= (on ENST00000563137 / NM_001379286.1; = p.R398= on NM_015069.4) | Silent (SNP) | VAF 61/552 reads (11%) | catalogued as COSV52176895, COSV52196230; called by muse, mutect2, varscan2
- ZNF543 | c.42G>T p.V14= | Silent (SNP) | VAF 43/336 reads (13%) | catalogued as rs947722536; called by muse, mutect2, varscan2
- ZNF608 | c.138G>A p.Q46= | Silent (SNP) | VAF 30/318 reads (9%) | called by muse, mutect2
- ZNF728 | c.801G>T p.R267= | Silent (SNP) | VAF 51/385 reads (13%) | called by muse, mutect2, varscan2
- AC079880.1 | n.1064G>C | RNA (SNP) | VAF 28/259 reads (11%) | called by muse, mutect2, varscan2
- ACP1 | c.-4del | 5'UTR (DEL) | VAF 18/170 reads (11%) | called by mutect2, varscan2
- ADAM22 | c.-45A>G | 5'UTR (SNP) | VAF 46/336 reads (14%) | catalogued as rs576741440, COSV55980832; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823836 C>A | 5'Flank (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2, varscan2
- AP1S1 | c.-21C>G | 5'UTR (SNP) | VAF 66/486 reads (14%) | called by muse, mutect2, varscan2
- ARPP21 | c.261+170G>C | Intron (SNP) | VAF 9/57 reads (16%) | catalogued as rs183848724; called by muse, mutect2, varscan2
- ASCC3 | c.241+4887G>A | Intron (SNP) | VAF 32/296 reads (11%) | catalogued as rs1562350284; called by muse, mutect2
- ASTN1 | c.2482+57del | Intron (DEL) | VAF 52/427 reads (12%) | called by mutect2, pindel, varscan2
- C9orf92 | n.109C>A | RNA (SNP) | VAF 46/188 reads (24%) | catalogued as rs903435381; called by muse, mutect2, varscan2
- CCDC74B | c.295+213G>T | Intron (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- CEP290 | c.1623+15C>T | Intron (SNP) | VAF 28/317 reads (9%) | catalogued as rs1256796451; called by muse, mutect2
- CYP4F12 | c.397+12C>A | Intron (SNP) | VAF 15/100 reads (15%) | called by muse, mutect2, varscan2
- DCHS2 | n.2610G>T | RNA (SNP) | VAF 16/187 reads (9%) | called by muse, mutect2
- DDX11 | c.2372+45G>T | Intron (SNP) | VAF 93/393 reads (24%) | called by muse, mutect2, varscan2
- DDX11 | c.2372+46G>T | Intron (SNP) | VAF 92/389 reads (24%) | called by muse, mutect2, varscan2
- DGKB | c.2307+12G>C | Intron (SNP) | VAF 63/246 reads (26%) | called by muse, mutect2, varscan2
- DHX16 | c.-157G>A | 5'UTR (SNP) | VAF 25/189 reads (13%) | called by muse, mutect2, varscan2
- DOC2A | c.-13-49C>A | Intron (SNP) | VAF 61/418 reads (15%) | called by muse, mutect2, varscan2
- ERGIC3 | c.880-49G>T | Intron (SNP) | VAF 22/176 reads (13%) | called by muse, varscan2
- ETFDH | c.-20G>C | 5'UTR (SNP) | VAF 30/312 reads (10%) | called by muse, mutect2
- FABP2 | c.*14C>T | 3'UTR (SNP) | VAF 22/251 reads (9%) | catalogued as rs559368273; called by muse, mutect2
- FOSL2 | c.-53G>A | 5'UTR (SNP) | VAF 59/327 reads (18%) | called by muse, mutect2, varscan2
- GGA1 | c.43+246C>T | Intron (SNP) | VAF 17/176 reads (10%) | called by muse, mutect2, varscan2
- KCNMA1 | c.2267-44G>T | Intron (SNP) | VAF 47/380 reads (12%) | catalogued as rs1465086963; called by muse, mutect2, varscan2
- LRRC27 | c.1416+1322G>A | Intron (SNP) | VAF 22/179 reads (12%) | called by muse, mutect2, varscan2
- LRRC37A6P | n.2020A>T | RNA (SNP) | VAF 40/399 reads (10%) | called by muse, mutect2
- LTBP3 | c.2978-50T>G | Intron (SNP) | VAF 34/274 reads (12%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-11071G>T | Intron (SNP) | VAF 20/155 reads (13%) | catalogued as COSV57105089, COSV57110719; called by muse, mutect2, varscan2
- MAP9 | c.708+75G>A | Intron (SNP) | VAF 38/94 reads (40%) | called by muse, mutect2, varscan2
- MIR520E | n.18C>A | RNA (SNP) | VAF 31/245 reads (13%) | called by muse, mutect2, varscan2
- MOB4P2 | chr11:86823587 C>A | 5'Flank (SNP) | VAF 31/223 reads (14%) | called by muse, mutect2, varscan2
- NIBAN1 | c.-74C>G | 5'UTR (SNP) | VAF 14/341 reads (4%) | called by muse, mutect2
- NOC2LP2 | n.1134C>T | RNA (SNP) | VAF 51/498 reads (10%) | called by muse, mutect2, varscan2
- NOL4L | c.*321G>C | 3'UTR (SNP) | VAF 22/206 reads (11%) | called by muse, mutect2
- NRXN1 | c.3719-1434C>A | Intron (SNP) | VAF 37/334 reads (11%) | called by muse, mutect2, varscan2
- OR51F5P | n.210C>T | RNA (SNP) | VAF 34/280 reads (12%) | called by muse, mutect2, varscan2
- OR51F5P | n.666G>C | RNA (SNP) | VAF 26/196 reads (13%) | called by muse, mutect2, varscan2
- PSMB7 | c.511+8494G>T | Intron (SNP) | VAF 26/232 reads (11%) | called by muse, mutect2, varscan2
- PTBP3 | c.8+669A>C | Intron (SNP) | VAF 9/128 reads (7%) | called by muse, mutect2
- RBM3 | c.211-24C>T | Intron (SNP) | VAF 88/313 reads (28%) | called by muse, mutect2, varscan2
- RBM44 | c.-98-2651C>A | Intron (SNP) | VAF 14/106 reads (13%) | catalogued as COSV57629538; called by muse, mutect2, varscan2
- RNU6-389P | chr7:55687783 G>T | 3'Flank (SNP) | VAF 21/159 reads (13%) | called by muse, mutect2
- SGIP1 | c.472-1171G>A | Intron (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- SLC3A1 | c.1136+64C>T | Intron (SNP) | VAF 40/324 reads (12%) | called by muse, mutect2, varscan2
- SLC66A1L | n.443+6264C>T | Intron (SNP) | VAF 8/124 reads (6%) | catalogued as rs1325844247, COSV100396537; called by muse, mutect2
- SNORD115-31 | n.55C>A | RNA (SNP) | VAF 26/342 reads (8%) | called by muse, mutect2
- SNORD116-25 | n.85T>A | RNA (SNP) | VAF 24/196 reads (12%) | called by muse, mutect2, varscan2
- SNURFL | n.211G>C | RNA (SNP) | VAF 23/152 reads (15%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.2404G>C | RNA (SNP) | VAF 65/618 reads (11%) | catalogued as rs564290956; called by muse, mutect2, varscan2
- SYCE1 | chr10:133568250 G>T | 5'Flank (SNP) | VAF 30/258 reads (12%) | called by muse, mutect2, varscan2
- TAF1B | chr2:9843444 C>T | 5'Flank (SNP) | VAF 15/122 reads (12%) | catalogued as rs954199892; called by muse, mutect2, varscan2
- TPRX2P | n.187G>A | RNA (SNP) | VAF 26/218 reads (12%) | catalogued as rs765663004; called by muse, mutect2, varscan2
- TXLNB | c.1077+108G>T | Intron (SNP) | VAF 26/197 reads (13%) | called by muse, mutect2, varscan2
- UBR7 | c.*1201G>A | 3'UTR (SNP) | VAF 71/567 reads (13%) | called by muse, mutect2, varscan2
- ZNF252P | n.2068C>T | RNA (SNP) | VAF 44/290 reads (15%) | called by muse, mutect2, varscan2
